Somatic mutation profile of tumor specimen TCGA-56-A49D-01A (aliquot TCGA-56-A49D-01A-11D-A24D-08) from TCGA case TCGA-56-A49D, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 67.7 years (24,745 days).
Specimen TCGA-56-A49D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eea4c504-161e-4669-b679-777ada9030fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-A49D-10A (Blood Derived Normal), aliquot TCGA-56-A49D-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c5304d8-0b46-42b7-90e0-2ef9020b51c9

The open-access MAF lists 326 somatic variants for this specimen: 242 protein-altering or splice-affecting, 74 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 211, Silent 74, Nonsense Mutation 18, Splice Site 4, RNA 4, Intron 3, Frame Shift Del 3, In Frame Del 2, Splice Region 2, In Frame Ins 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K4 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | hotspot (GDC flag); catalogued as rs1164096095, COSV62258353; called by muse, mutect2, varscan2
- PTEN | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 35/86 reads (41%) | catalogued as rs121909227, CM981672, COSV64290622; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TGFBR1 | c.696G>C p.K232N | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs863223811, COSV66625008, COSV66626875; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.394A>C p.K132Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs747342068, CM086989, CM973641, COSV52689323, COSV52708494, COSV52979406, COSV53353999; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.1170C>G p.I390M | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.872); catalogued as rs748262552, COSV99711476; called by muse, mutect2, varscan2
- ABCC10 | c.3379G>C p.E1127Q (on ENST00000372530 / NM_001198934.2; = p.E1099Q on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); catalogued as rs1309509001, COSV99768140; called by muse, mutect2, varscan2
- ACOX1 | c.809G>T p.S270I | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV99504069; called by muse, mutect2, varscan2
- ACSM1 | c.77A>G p.Q26R | Missense Mutation (SNP) | VAF 88/249 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99533529; called by muse, mutect2, varscan2
- ACTRT1 | c.1053C>A p.S351R | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV100947792; called by muse, mutect2, varscan2
- ADAM19 | c.1566G>T p.Q522H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.837); catalogued as COSV57423590, COSV99978732; called by muse, mutect2, varscan2
- ADCY8 | c.1226G>T p.R409L | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as rs756790618, COSV53897846, COSV99654838; called by muse, mutect2, varscan2
- ADGRF2 | c.903C>A p.N301K (on ENST00000296862 / NM_001368115.2; = p.N233K on NM_153839.7) | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.085); catalogued as COSV57287024, COSV99731990; called by muse, mutect2, varscan2
- AFF2 | c.1379C>A p.P460H | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.866); catalogued as COSV99666837; called by muse, mutect2, varscan2
- AKAP9 | c.5795G>C p.R1932P (on ENST00000359028; = p.R1900P on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV100663308; called by muse, mutect2, varscan2
- ALS2 | c.2968C>A p.P990T | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.917); catalogued as rs1187454413, COSV99970172; called by muse, mutect2, varscan2
- ANKRD44 | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 90/336 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99986185; called by muse, mutect2, varscan2
- ANO5 | c.2081C>A p.P694H | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100202318; called by muse, mutect2, varscan2
- ARHGAP35 | c.2625T>A p.C875* | Nonsense Mutation (SNP) | VAF 31/125 reads (25%) | catalogued as COSV101351864; called by muse, mutect2, varscan2
- ARMC4 | c.2627T>C p.V876A | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV100537498; called by muse, mutect2, varscan2
- ASCC1 | c.116C>G p.S39C | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.598); catalogued as COSV100403602, COSV100403885; called by muse, mutect2, varscan2
- ATAD2B | c.2470C>T p.R824* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | catalogued as COSV53198223, COSV99478639; called by muse, mutect2, varscan2
- ATM | c.4117G>A p.D1373N | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV99592374; called by muse, mutect2, varscan2
- ATM | c.4642G>C p.D1548H | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as CD961801, COSV99592376; called by muse, mutect2, varscan2
- B3GALT1 | c.403C>G p.Q135E | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0.01); catalogued as COSV100003162; called by muse, mutect2, varscan2
- BAHCC1 | c.6805G>A p.G2269R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.805); catalogued as rs374335021; called by muse, mutect2, varscan2
- BHMT | c.181C>G p.R61G | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as rs780760620, COSV99165567; called by muse, mutect2, varscan2
- BMP4 | c.608G>C p.R203T | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99817185; called by muse, mutect2, varscan2
- BPIFB4 | c.629G>T p.G210V | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100971682; called by muse, mutect2, varscan2
- BRMS1 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as COSV60820597; called by muse, mutect2, varscan2
- BTG3 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as COSV100336405; called by muse, mutect2, varscan2
- C3 | c.4585C>A p.L1529M | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as COSV99837397; called by muse, mutect2, varscan2
- C6 | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs867408360, COSV54706337; called by muse, mutect2, varscan2
- CACNG2 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 61/248 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100269155; called by muse, mutect2, varscan2
- CADM2 | c.244G>C p.A82P (on ENST00000407528 / NM_001167674.2; = p.A84P on NM_153184.4) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV67356397, COSV67409263; called by muse, mutect2
- CALCR | c.1364C>A p.P455Q (on ENST00000649521 / NM_001164737.2; = p.P439Q on NM_001742.4) | Missense Mutation (SNP) | VAF 54/234 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as COSV100810909; called by muse, mutect2, varscan2
- CARMIL2 | c.4184C>T p.S1395F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV99538045; called by muse, mutect2, varscan2
- CASP8AP2 | c.461G>A p.R154K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs763942297, COSV52748369; called by muse, mutect2
- CAV3 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.166); catalogued as rs139786391; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CBLL2 | c.5A>G p.N2S | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.162); catalogued as COSV100081792; called by muse, mutect2, varscan2
- CCDC186 | c.2103A>G p.A701= | Splice Region (SNP) | VAF 42/81 reads (52%) | catalogued as COSV100991148; called by muse, mutect2, varscan2
- CD300E | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as rs867573915, COSV100151574; called by muse, mutect2
- CD93 | c.1499C>A p.A500D | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99849692; called by muse, mutect2, varscan2
- CDH19 | c.1304G>A p.W435* | Nonsense Mutation (SNP) | VAF 29/54 reads (54%) | catalogued as COSV100052537; called by muse, mutect2, varscan2
- CDX4 | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100999136; called by muse, mutect2, varscan2
- CELSR1 | c.8179G>A p.A2727T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0.014); catalogued as rs377639775; called by muse, varscan2
- CEP83 | c.213G>T p.K71N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV100353324; called by muse, mutect2, varscan2
- CFAP44 | c.2170G>T p.E724* | Nonsense Mutation (SNP) | VAF 36/105 reads (34%) | catalogued as COSV99870467; called by muse, mutect2, varscan2
- CHD1 | c.3368T>G p.I1123S | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV99400026; called by muse, mutect2, varscan2
- CHST6 | c.349C>G p.L117V | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.76); PolyPhen benign (0.012); catalogued as COSV100178652; called by muse, mutect2, varscan2
- CKAP2L | c.2146G>C p.E716Q | Missense Mutation (SNP) | VAF 67/230 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as COSV100198825, COSV56698478; called by muse, mutect2, varscan2
- CLDN12 | c.457T>C p.W153R | Missense Mutation (SNP) | VAF 51/205 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99842270; called by muse, mutect2, varscan2
- CNGA2 | c.943C>A p.P315T | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV100323996; called by muse, mutect2, varscan2
- CNOT1 | c.1774C>T p.R592C | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57784161; called by muse, mutect2, varscan2
- CNTN5 | c.2671G>C p.E891Q | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV99682262; called by muse, mutect2
- COL15A1 | c.344A>G p.Q115R | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as COSV100898063; called by muse, mutect2, varscan2
- COL1A2 | c.3461G>T p.G1154V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99801420; called by muse, mutect2, varscan2
- COL22A1 | c.2559+1G>T p.X853_splice | Splice Site (SNP) | VAF 25/58 reads (43%) | catalogued as COSV100281199; called by muse, mutect2, varscan2
- COL6A3 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs188510971, COSV99802225; called by muse, mutect2, varscan2
- COL9A2 | c.1510C>T p.R504* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as rs781682527, COSV101028810; called by muse, varscan2
- COPE | c.827A>T p.Q276L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99447932; called by muse, mutect2, varscan2
- CPED1 | c.1849C>G p.L617V | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100121635; called by muse, mutect2, varscan2
- CPS1 | c.2807A>T p.N936I | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV99244375; called by muse, mutect2, varscan2
- CSMD2 | c.5475G>T p.K1825N | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV53911876, COSV53921022; called by muse, mutect2, varscan2
- CUBN | c.10765-2A>G p.X3589_splice | Splice Site (SNP) | VAF 8/21 reads (38%) | catalogued as COSV100913707; called by muse, varscan2
- CYP4F8 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 17/49 reads (35%) | catalogued as COSV100358275; called by muse, mutect2, varscan2
- CYP7A1 | c.747G>C p.K249N | Missense Mutation (SNP) | VAF 79/388 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as rs767634039, COSV100052674; called by muse, mutect2, varscan2
- CYTIP | c.364T>G p.C122G | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.065); catalogued as COSV51633239, COSV99938965; called by muse, mutect2
- DDN | c.874G>T p.G292C | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100305540; called by muse, mutect2, varscan2
- DEFB121 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.075); catalogued as COSV100889996; called by muse, mutect2
- DHCR7 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100831843, COSV100832185; called by muse, mutect2, varscan2
- DHDDS | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99360704; called by muse, mutect2, varscan2
- DHRS9 | c.810C>A p.H270Q | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100513731; called by muse, mutect2, varscan2
- DIAPH1 | c.2472G>C p.K824N | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99527374; called by muse, mutect2, varscan2
- DISP1 | c.2455G>A p.A819T | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs201957626, COSV99451840; called by muse, mutect2, varscan2
- DNAH3 | c.8359T>G p.S2787A | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as COSV99771212; called by muse, mutect2
- DSCAML1 | c.1885G>T p.D629Y (on ENST00000321322; = p.D569Y on NM_020693.4) | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58396943; called by muse, mutect2, varscan2
- DSG1 | c.1640G>T p.G547V | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57134285; called by muse, mutect2, varscan2
- DYNC2H1 | c.3625C>T p.H1209Y | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100519978; called by muse, mutect2, varscan2
- DYTN | c.1112A>T p.K371M | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV101510916; called by muse, mutect2, varscan2
- EDIL3 | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV99679590; called by muse, mutect2, varscan2
- EFCAB6 | c.2381G>T p.S794I | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV99414640; called by muse, mutect2, varscan2
- EHHADH | c.1246G>C p.D416H | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99213404; called by muse, mutect2, varscan2
- ELMOD1 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as COSV99760521; called by muse, mutect2, varscan2
- EPPIN-WFDC6 | c.520A>G p.K174E | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.074); catalogued as rs201334841, COSV100323409; called by muse, mutect2, varscan2
- FAM110B | c.189G>C p.K63N | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100826298; called by muse, mutect2, varscan2
- FBXL12 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.157); catalogued as COSV99928177; called by muse, mutect2, varscan2
- FNDC3B | c.2844G>C p.Q948H | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100395151; called by muse, mutect2, varscan2
- FOLH1 | c.513G>T p.E171D | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV99924072; called by muse, mutect2, varscan2
- FRMD1 | c.1517C>A p.T506N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1460323093, COSV99350207; called by muse, mutect2, varscan2
- FRMPD1 | c.2705T>C p.L902S | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1192012449, COSV100899671; called by muse, mutect2, varscan2
- GAL3ST3 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100360718; called by muse, mutect2, varscan2
- GARS1 | c.991A>G p.R331G | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101220313; called by muse, mutect2, varscan2
- GAS2 | c.551C>G p.P184R | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.535); catalogued as COSV99535871; called by muse, mutect2, varscan2
- GAS6 | c.1082A>G p.Y361C | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.166); catalogued as COSV100582346; called by muse, mutect2, varscan2
- GCG | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs745474532, COSV100972878; called by muse, mutect2, varscan2
- GNE | c.661C>T p.L221F (on ENST00000396594 / NM_001128227.3; = p.L190F on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as rs886042560, CM108345, COSV100930160; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GNL2 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV100895054; called by muse, mutect2, varscan2
- GPCPD1 | c.1366A>G p.I456V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100980267; called by muse, mutect2, varscan2
- GPR135 | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.309); catalogued as rs773869142, COSV101229334, COSV101229361; called by muse, mutect2, varscan2
- GPT2 | c.60G>T p.W20C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.113); catalogued as COSV100413114; called by muse, mutect2
- GRM3 | c.1151A>C p.Y384S | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100862986; called by muse, mutect2, varscan2
- GTF3C3 | c.1390+1G>T p.X464_splice | Splice Site (SNP) | VAF 13/54 reads (24%) | catalogued as COSV99827104; called by muse, mutect2, varscan2
- HCN1 | c.439T>G p.L147V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV100302739; called by muse, mutect2, varscan2
- HDLBP | c.626G>T p.R209L | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.428); catalogued as COSV100192040; called by muse, mutect2, varscan2
- IFNLR1 | c.279C>G p.Y93* | Nonsense Mutation (SNP) | VAF 27/123 reads (22%) | catalogued as COSV100552339; called by muse, mutect2, varscan2
- IQSEC1 | c.1481G>T p.S494I | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99832521; called by muse, mutect2, varscan2
- ITGAD | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101210612; called by muse, mutect2, varscan2
- ITK | c.1410G>T p.M470I | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101439906; called by muse, mutect2, varscan2
- KCNK10 | c.1402G>T p.D468Y | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV56652447; called by muse, mutect2, varscan2
- KIF24 | c.3503G>A p.G1168D | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV99903661; called by muse, mutect2, varscan2
- KRT79 | c.666C>A p.N222K | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.234); catalogued as COSV100398296, COSV100398579; called by muse, mutect2, varscan2
- LHFPL3 | c.320C>G p.A107G | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV101309063; called by muse, mutect2, varscan2
- LILRB2 | c.748G>T p.G250C | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs188407464, COSV100079732; called by muse, mutect2, varscan2
- LRP1B | c.7067T>A p.V2356E | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV101262066; called by muse, mutect2, varscan2
- LRP2 | c.3050C>A p.P1017Q | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV99790646; called by muse, mutect2, varscan2
- LRRC4C | c.731A>G p.H244R | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV53438858; called by muse, mutect2, varscan2
- LRRC7 | c.3968G>A p.R1323K (on ENST00000651989 / NM_001370785.2; = p.R1290K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.632); catalogued as COSV50450898, COSV99230393; called by muse, mutect2, varscan2
- LRRIQ3 | c.1495G>T p.E499* | Nonsense Mutation (SNP) | VAF 13/91 reads (14%) | catalogued as COSV100599576, COSV63042485; called by muse, mutect2, varscan2
- MAGEC1 | c.2473C>A p.L825I | Missense Mutation (SNP) | VAF 101/190 reads (53%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.134); catalogued as COSV99596765; called by muse, mutect2, varscan2
- MAGEC3 | c.867T>A p.C289* | Nonsense Mutation (SNP) | VAF 69/141 reads (49%) | catalogued as COSV100026251; called by muse, mutect2, varscan2
- MFN2 | c.2233C>T p.L745F | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as COSV99337162; called by muse, mutect2, varscan2
- MFSD1 | c.428G>C p.R143T | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51839862, COSV99964142; called by muse, mutect2, varscan2
- MIPEP | c.1392A>C p.Q464H | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101193283; called by muse, mutect2, varscan2
- MKI67 | c.6700A>G p.I2234V | Missense Mutation (SNP) | VAF 231/415 reads (56%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as rs748281750, COSV100897066; called by muse, mutect2, varscan2
- MMP16 | c.899C>A p.T300K | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.271); catalogued as COSV99690788; called by muse, mutect2, varscan2
- MMRN1 | c.3157G>T p.G1053W | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99307520; called by muse, mutect2, varscan2
- MOSPD3 | c.5G>C p.R2P | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.418); catalogued as COSV99775045; called by muse, mutect2, varscan2
- MPHOSPH9 | c.2781A>T p.Q927H | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV100187360, COSV56617059; called by muse, mutect2, varscan2
- MRPS12 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.181); catalogued as rs769557703, COSV99671657; called by muse, mutect2, varscan2
- MRPS18A | c.512G>A p.R171K | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100928789; called by muse, mutect2, varscan2
- MTMR8 | c.1566A>T p.K522N | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100878678; called by muse, mutect2, varscan2
- MYH13 | c.533C>T p.T178I | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs766342832, COSV99355831; called by muse, mutect2, varscan2
- MYH4 | c.4366-1G>A p.X1456_splice | Splice Site (SNP) | VAF 17/68 reads (25%) | catalogued as COSV55115371, COSV99702480; called by muse, mutect2, varscan2
- MYH6 | c.4960G>A p.D1654N | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs767658491, COSV100677078; called by muse, mutect2, varscan2
- MYO16 | c.3802G>A p.V1268I | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs377315850, COSV100695852; called by muse, mutect2, varscan2
- MYO1B | c.1066C>T p.L356F | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100270270; called by muse, mutect2
- NDST4 | c.121A>C p.M41L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99997501, COSV99998224; called by muse, mutect2, varscan2
- NEB | c.5119G>C p.A1707P | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99428829; called by muse, mutect2
- NLRP8 | c.2036G>T p.G679V | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as COSV99406100; called by muse, mutect2, varscan2
- NMD3 | c.1503G>A p.M501I | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs1560077131, COSV100664843; called by muse, mutect2, varscan2
- NRXN2 | c.1195C>T p.L399= | Splice Region (SNP) | VAF 7/27 reads (26%) | catalogued as COSV99636298; called by muse, mutect2, varscan2
- NTRK2 | c.433C>A p.L145M | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99459200; called by muse, mutect2, varscan2
- NUP210L | c.4910C>G p.S1637* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | catalogued as COSV99669320; called by muse, mutect2, varscan2
- NXPE4 | c.154T>A p.S52T | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.108); catalogued as COSV100970584; called by muse, mutect2, varscan2
- OR10K2 | c.532T>A p.F178I | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100149699; called by muse, mutect2, varscan2
- OR10W1 | c.104T>A p.L35H | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV101223809; called by muse, mutect2, varscan2
- OR4X2 | c.58T>G p.F20V | Missense Mutation (SNP) | VAF 56/167 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as COSV56585535; called by muse, mutect2, varscan2
- OR5AR1 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 69/301 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV100265848; called by muse, mutect2, varscan2
- OR5J2 | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56623062; called by muse, mutect2, varscan2
- OR7C2 | c.850C>A p.L284M | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV99934673; called by muse, mutect2, varscan2
- OR8U1 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs1410063623, COSV100164170; called by muse, mutect2, varscan2
- P2RY8 | c.482C>A p.T161N | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV101184220; called by muse, mutect2, varscan2
- PADI2 | c.1915C>A p.H639N | Missense Mutation (SNP) | VAF 65/257 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100972076; called by muse, mutect2, varscan2
- PARP4 | c.3190G>C p.D1064H | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.436); catalogued as rs140105951, COSV101132141; called by muse, mutect2
- PASK | c.828C>A p.D276E | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs753287024, COSV99300426; called by muse, mutect2, varscan2
- PCARE | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1253679295, COSV59053048; called by muse, mutect2, varscan2
- PCDH10 | c.2671A>T p.R891* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99994726; called by muse, mutect2, varscan2
- PIGO | c.762G>T p.Q254H | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99957004; called by muse, mutect2, varscan2
- PKD1L2 | c.2548G>A p.A850T | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.523); catalogued as COSV100217190; called by muse, mutect2, varscan2
- PLCB3 | c.892C>G p.R298G | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.946); catalogued as COSV99657815; called by muse, mutect2, varscan2
- PRKCB | c.945G>T p.K315N | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100335600; called by muse, mutect2, varscan2
- PRLR | c.1828G>T p.D610Y | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1236324669, COSV99184867; called by muse, mutect2, varscan2
- PTGFR | c.1043C>G p.S348C | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV100882364; called by muse, mutect2, varscan2
- RBMS3 | c.355G>T p.V119L | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV99824781; called by muse, mutect2, varscan2
- RETREG2 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 94/215 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs1398513856, COSV56087450, COSV56089450; called by muse, varscan2
- REXO5 | c.1549A>G p.N517D | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as COSV99759555; called by muse, mutect2, varscan2
- RNF125 | c.294G>C p.K98N | Missense Mutation (SNP) | VAF 80/134 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV54186508; called by muse, mutect2, varscan2
- RNF186 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 55/207 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as rs763892906, COSV100909127; called by muse, mutect2, varscan2
- RNF213 | c.14850G>T p.E4950D | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.099); catalogued as CM116648, COSV100301676; called by muse, mutect2, varscan2
- SF3A3 | c.1328C>T p.T443I | Missense Mutation (SNP) | VAF 55/223 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100885707; called by muse, mutect2, varscan2
- SIGLEC10 | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.065); catalogued as rs777376006, COSV100219502; called by muse, mutect2, varscan2
- SKIV2L | c.2407G>A p.G803S | Missense Mutation (SNP) | VAF 84/156 reads (54%) | SIFT tolerated (0.41); PolyPhen benign (0.33); catalogued as COSV100514872; called by muse, mutect2, varscan2
- SLC17A6 | c.1549G>C p.G517R | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV99582550; called by muse, mutect2, varscan2
- SLC1A4 | c.1497C>G p.N499K | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT tolerated (0.92); PolyPhen benign (0.05); catalogued as COSV99309267; called by muse, mutect2, varscan2
- SLC28A3 | c.1472T>C p.M491T | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.345); catalogued as COSV100883365; called by muse, mutect2, varscan2
- SLIT1 | c.298G>T p.V100L | Missense Mutation (SNP) | VAF 362/639 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.187); catalogued as COSV99822753; called by muse, mutect2, varscan2
- SMARCC1 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); catalogued as COSV99593622; called by muse, mutect2, varscan2
- SMC4 | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.122); catalogued as COSV100644151; called by muse, mutect2, varscan2
- SMG7 | c.2378A>G p.Q793R | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.265); catalogued as COSV100750631; called by muse, mutect2, varscan2
- SORCS3 | c.1061T>A p.L354Q | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100865712; called by muse, mutect2, varscan2
- SP1 | c.1054C>G p.Q352E (on ENST00000327443 / NM_138473.3; = p.Q345E on NM_003109.1) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV100540894; called by muse, mutect2, varscan2
- SPEM1 | c.922G>T p.G308W | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV100081323; called by muse, mutect2, varscan2
- SPINK6 | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760970575, COSV100347214; called by mutect2, varscan2
- SPTBN5 | c.10813A>T p.R3605W | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV100312376; called by muse, mutect2, varscan2
- ST18 | c.189C>A p.H63Q | Missense Mutation (SNP) | VAF 46/287 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99391350; called by muse, mutect2, varscan2
- STAT4 | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV100636265; called by muse, mutect2
- STON1 | c.478G>T p.A160S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.006); catalogued as rs1210869009, COSV100562355; called by muse, mutect2, varscan2
- SYNE1 | c.5734G>A p.A1912T (on ENST00000367255 / NM_182961.4; = p.A1919T on NM_033071.3) | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.057); catalogued as COSV99583143; called by muse, mutect2, varscan2
- SYNE2 | c.9341C>G p.S3114* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as COSV100648595; called by muse, mutect2, varscan2
- TAAR8 | c.955A>G p.K319E | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV99257394; called by muse, mutect2, varscan2
- TET2 | c.238C>G p.Q80E | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV54415206, COSV99485275; called by muse, mutect2, varscan2
- THSD7B | c.3616G>C p.G1206R (on ENST00000272643; = p.G1204R on NM_001316349.2) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99759200; called by muse, mutect2, varscan2
- TMEM132A | c.259T>C p.W87R | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV99137666; called by muse, mutect2, varscan2
- TOGARAM1 | c.5032A>T p.T1678S | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100818302; called by muse, mutect2, varscan2
- TRHDE | c.2682C>G p.C894W | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99672997; called by muse, mutect2, varscan2
- TRIOBP | c.3515C>T p.P1172L | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100730739; called by muse, mutect2, varscan2
- TTN | c.79929C>G p.I26643M (on ENST00000591111; = p.I19219M on NM_003319.4) | Missense Mutation (SNP) | VAF 20/79 reads (25%) | PolyPhen possibly damaging (0.748); catalogued as COSV100634301, COSV60001824; called by muse, mutect2, varscan2
- TTN | c.74110T>G p.S24704A (on ENST00000591111; = p.S17280A on NM_003319.4) | Missense Mutation (SNP) | VAF 23/115 reads (20%) | PolyPhen benign (0.033); catalogued as COSV100634303; called by muse, mutect2, varscan2
- TTN | c.56288T>A p.L18763Q (on ENST00000591111; = p.L11339Q on NM_003319.4) | Missense Mutation (SNP) | VAF 48/147 reads (33%) | PolyPhen probably damaging (0.999); catalogued as COSV100634304; called by muse, mutect2, varscan2
- TTN | c.45416G>T p.G15139V (on ENST00000591111; = p.G7715V on NM_003319.4) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | PolyPhen probably damaging (1); catalogued as COSV100634307; called by muse, mutect2, varscan2
- TTN | c.4570G>T p.D1524Y (on ENST00000591111; = p.D1478Y on NM_003319.4) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | PolyPhen probably damaging (0.999); catalogued as COSV100634311, COSV59883530; called by muse, mutect2, varscan2
- TUT7 | c.3238A>G p.I1080V | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as COSV99463820; called by muse, mutect2, varscan2
- TXNL1 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as COSV99469968; called by muse, mutect2, varscan2
- UBB | c.382G>C p.D128H | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV100141742; called by muse, mutect2, varscan2
- UBR5 | c.3467G>A p.G1156E | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs952256588, COSV99642632; called by muse, mutect2, varscan2
- UNC13A | c.3508C>T p.R1170* | Nonsense Mutation (SNP) | VAF 22/74 reads (30%) | catalogued as rs1381699671, COSV99409824; called by muse, mutect2, varscan2
- UNC45B | c.2089G>T p.A697S | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.578); catalogued as COSV99269363; called by muse, mutect2, varscan2
- UNC5D | c.1151C>A p.S384* | Nonsense Mutation (SNP) | VAF 61/248 reads (25%) | catalogued as COSV99779463; called by muse, mutect2, varscan2
- UNC93A | c.226T>A p.C76S | Missense Mutation (SNP) | VAF 62/552 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV100023736; called by muse, mutect2, varscan2
- USH2A | c.8113C>G p.L2705V | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.138); catalogued as COSV100243804; called by muse, mutect2, varscan2
- USP33 | c.1723G>C p.A575P | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100657276; called by muse, mutect2
- VN1R4 | c.776T>C p.L259S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as COSV100237628; called by muse, mutect2, varscan2
- VPS13B | c.5425G>C p.E1809Q | Missense Mutation (SNP) | VAF 77/186 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV100663931; called by muse, mutect2, varscan2
- VSIG1 | c.1064A>G p.Q355R | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV99480511; called by muse, mutect2, varscan2
- WDHD1 | c.661C>T p.Q221* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100864511; called by muse, mutect2, varscan2
- XIRP2 | c.6171C>A p.H2057Q (on ENST00000628543; = p.H2232Q on NM_152381.6) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs370981896, COSV54681914; called by muse, mutect2, varscan2
- ZC3H12C | c.1579A>G p.T527A | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV99585420; called by muse, mutect2, varscan2
- ZDBF2 | c.5586C>A p.D1862E | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.257); catalogued as COSV100985664; called by muse, mutect2, varscan2
- ZFYVE1 | c.1067C>A p.S356Y | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100607192; called by muse, mutect2, varscan2
- ZIM2 | c.1583G>C p.*528Sext*21 | Nonstop Mutation (SNP) | VAF 19/67 reads (28%) | catalogued as COSV99690766; called by muse, mutect2, varscan2
- ZNF197 | c.1978A>G p.I660V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.069); catalogued as rs942936525, COSV100482312; called by muse, mutect2, varscan2
- ZNF224 | c.629G>A p.G210D | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV61242732; called by muse, mutect2, varscan2
- ZNF484 | c.1491A>G p.I497M | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as COSV100214937; called by muse, mutect2, varscan2
- ZNF507 | c.1812C>G p.D604E | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100322189; called by muse, mutect2, varscan2
- ZNF536 | c.11C>A p.A4E | Missense Mutation (SNP) | VAF 39/210 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.148); catalogued as COSV62823455; called by muse, mutect2, varscan2
- ZNF638 | c.1190C>T p.S397L | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.194); catalogued as COSV100040227; called by muse, mutect2, varscan2
- ZNF665 | c.169G>C p.G57R (on ENST00000600412; = p.G122R on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV101128931; called by muse, mutect2, varscan2
- ZNF821 | c.862G>T p.E288* (on ENST00000425432 / NM_001376297.1; = p.E246* on NM_017530.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 18/68 reads (26%) | catalogued as COSV100546937; called by muse, mutect2, varscan2
- ZRANB2 | c.326G>C p.R109T | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99639425; called by muse, mutect2, varscan2
- CASP7 | c.533_538del p.P178_K179del | In Frame Del (DEL) | VAF 13/41 reads (32%) | called by mutect2, pindel, varscan2
- CNTN4 | c.2536A>G p.K846E | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- EML1 | c.778_789del p.E260_L263del | In Frame Del (DEL) | VAF 14/78 reads (18%) | called by pindel, varscan2
- GDF10 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- LILRB3 | c.141C>G p.I47M | Missense Mutation (SNP) | VAF 40/338 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- MCM2 | c.1651del p.A551Rfs*42 | Frame Shift Del (DEL) | VAF 40/261 reads (15%) | called by mutect2, pindel, varscan2
- MRC1 | c.2690A>T p.E897V | Missense Mutation (SNP) | VAF 65/203 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- OR8G2P | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 57/217 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OR8H1 | c.840_842dup p.V280_I281insM | In Frame Ins (INS) | VAF 17/78 reads (22%) | called by mutect2, pindel, varscan2
- SDS | c.82T>G p.Y28D | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- SRCIN1 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- UXS1 | c.659del p.G220Afs*3 | Frame Shift Del (DEL) | VAF 20/97 reads (21%) | called by mutect2, pindel, varscan2
- ZNF430 | c.1220del p.G407Afs*43 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- ADAM23 | c.2007A>T p.P669= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV52225382; called by muse, mutect2, varscan2
- ADAMTS8 | c.2442T>C p.F814= | Silent (SNP) | VAF 118/432 reads (27%) | catalogued as rs1410547334, COSV99961706; called by muse, mutect2, varscan2
- ADGRB3 | c.2907T>A p.A969= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV99487169; called by muse, mutect2, varscan2
- ANK1 | c.3018C>T p.L1006= | Silent (SNP) | VAF 46/232 reads (20%) | catalogued as COSV99227200; called by muse, mutect2, varscan2
- ANO5 | c.2082T>A p.P694= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as COSV100202320; called by muse, mutect2, varscan2
- ARID5A | c.1590C>T p.V530= | Silent (SNP) | VAF 65/175 reads (37%) | catalogued as COSV62591692; called by muse, mutect2, varscan2
- BRWD1 | c.3057C>G p.L1019= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs749716246, COSV100314322; called by muse, mutect2, varscan2
- BZW2 | c.69G>A p.E23= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV51755943; called by muse, mutect2, varscan2
- C7orf26 | c.609T>C p.L203= | Silent (SNP) | VAF 80/266 reads (30%) | catalogued as COSV100733027; called by muse, mutect2, varscan2
- CBR4 | c.117C>T p.A39= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs1307181852, COSV100085908; called by muse, mutect2, varscan2
- CDH13 | c.69A>G p.E23= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV99232015; called by muse, mutect2, varscan2
- CENPB | c.192C>T p.T64= | Silent (SNP) | VAF 46/117 reads (39%) | catalogued as COSV100713637; called by muse, mutect2, varscan2
- CFL1 | c.228A>G p.P76= | Silent (SNP) | VAF 51/200 reads (26%) | catalogued as rs1317894123, COSV100354208; called by muse, mutect2, varscan2
- CHCHD3 | c.342G>A p.E114= | Silent (SNP) | VAF 32/106 reads (30%) | catalogued as COSV99367025; called by muse, mutect2, varscan2
- CTSL | c.939G>A p.K313= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV100446766; called by muse, mutect2, varscan2
- DLK1 | c.747G>A p.A249= | Silent (SNP) | VAF 32/113 reads (28%) | catalogued as rs778635865, COSV57991433, COSV57992387; called by muse, mutect2, varscan2
- ETS1 | c.942C>G p.L314= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV100091549; called by muse, mutect2, varscan2
- F11R | c.444G>C p.R148= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV99231343; called by muse, mutect2, varscan2
- F8 | c.1644G>A p.L548= | Silent (SNP) | VAF 65/103 reads (63%) | catalogued as COSV100812093; called by muse, mutect2, varscan2
- FASTKD2 | c.93C>T p.F31= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV99379325; called by muse, mutect2, varscan2
- FGF10 | c.519G>T p.G173= | Silent (SNP) | VAF 37/130 reads (28%) | catalogued as COSV99241058; called by muse, mutect2, varscan2
- FREM2 | c.2505C>A p.T835= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as COSV54842624, COSV99751443; called by muse, mutect2, varscan2
- FRMPD2 | c.495G>C p.V165= | Silent (SNP) | VAF 46/131 reads (35%) | catalogued as COSV100564291; called by muse, mutect2, varscan2
- GFRA1 | c.489C>A p.L163= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as COSV100816284; called by muse, mutect2, varscan2
- GLP2R | c.1491T>A p.L497= | Silent (SNP) | VAF 31/122 reads (25%) | catalogued as COSV99302586; called by muse, mutect2, varscan2
- HSPB11 | c.18C>G p.L6= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99524119; called by muse, mutect2, varscan2
- IGF2R | c.1437C>T p.D479= | Silent (SNP) | VAF 81/232 reads (35%) | catalogued as rs201174713; called by muse, mutect2, varscan2
- IGHG2 | c.744C>A p.V248= | Silent (SNP) | VAF 65/287 reads (23%) | called by muse, varscan2
- KRT6A | c.834C>T p.Y278= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as rs1188634615, COSV100417297; called by muse, mutect2, varscan2
- LINGO1 | c.1764C>T p.N588= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs1405222535, COSV100796541; called by muse, mutect2, varscan2
- LRRIQ3 | c.1348C>A p.R450= | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as COSV100599578, COSV63041706; called by muse, mutect2, varscan2
- MAP4K1 | c.1665C>T p.L555= | Silent (SNP) | VAF 70/246 reads (28%) | catalogued as COSV67709598, COSV67709883; called by muse, mutect2, varscan2
- MARCO | c.414T>A p.T138= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100503913; called by muse, mutect2
- MIOS | c.2373T>C p.N791= | Silent (SNP) | VAF 45/146 reads (31%) | catalogued as rs1381619687, COSV100402996; called by muse, mutect2, varscan2
- MMRN1 | c.528T>C p.N176= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as COSV99307917; called by muse, mutect2, varscan2
- NPR1 | c.1461G>A p.L487= | Silent (SNP) | VAF 37/94 reads (39%) | catalogued as COSV100902089; called by muse, mutect2, varscan2
- NXPE4 | c.153G>A p.K51= | Silent (SNP) | VAF 56/206 reads (27%) | catalogued as COSV100970585; called by muse, mutect2, varscan2
- OR13A1 | c.942G>A p.E314= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as rs1393024828, COSV100981115; called by muse, mutect2, varscan2
- PHLDB2 | c.1080G>A p.V360= | Silent (SNP) | VAF 36/181 reads (20%) | catalogued as rs749087250, COSV101208774; called by muse, mutect2, varscan2
- PKHD1L1 | c.2673C>T p.P891= | Silent (SNP) | VAF 50/130 reads (38%) | catalogued as COSV101007012; called by muse, mutect2, varscan2
- PLCG2 | c.2175C>G p.L725= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as COSV100842708; called by muse, mutect2, varscan2
- PLEKHM2 | c.2784G>T p.P928= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV53818543, COSV99606850; called by muse, varscan2
- PLOD2 | c.1227A>G p.Q409= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV99283425; called by mutect2, varscan2
- POU4F1 | c.174C>A p.A58= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV101020611; called by muse, mutect2, varscan2
- PSMA2 | c.704A>G p.*235= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV99786099; called by muse, mutect2, varscan2
- PTPRM | c.888C>T p.T296= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as rs1424567740, COSV100161192; called by muse, mutect2, varscan2
- QSER1 | c.4251T>C p.D1417= (on ENST00000399302; = p.D1546= on NM_001076786.3) | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV101234991; called by muse, mutect2, varscan2
- RYR2 | c.12067C>T p.L4023= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100773225; called by muse, mutect2, varscan2
- SCFD1 | c.1128T>G p.S376= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV100356655; called by muse, mutect2, varscan2
- SFMBT2 | c.786G>A p.L262= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as COSV100739760; called by muse, mutect2, varscan2
- SLC22A6 | c.1248C>A p.P416= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV100842909; called by muse, mutect2, varscan2
- SLC2A7 | c.549A>T p.A183= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV101280844; called by muse, mutect2, varscan2
- SLC6A14 | c.1389C>T p.L463= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV100903246; called by muse, mutect2, varscan2
- SP1 | c.1602C>A p.L534= (on ENST00000327443 / NM_138473.3; = p.L527= on NM_003109.1) | Silent (SNP) | VAF 47/119 reads (39%) | catalogued as COSV100540896; called by muse, mutect2, varscan2
- SP4 | c.2127C>T p.C709= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs756715060; called by muse, mutect2
- TAS2R60 | c.888G>T p.L296= | Silent (SNP) | VAF 50/221 reads (23%) | catalogued as COSV60330077; called by muse, mutect2, varscan2
- TECTA | c.3540G>A p.V1180= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV99881858; called by muse, mutect2, varscan2
- THOC1 | c.462C>G p.V154= | Silent (SNP) | VAF 25/37 reads (68%) | catalogued as COSV99863650; called by muse, mutect2, varscan2
- TMF1 | c.1143T>C p.N381= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as COSV101275478; called by muse, mutect2, varscan2
- TPX2 | c.1272G>A p.V424= | Silent (SNP) | VAF 40/295 reads (14%) | catalogued as COSV100302160; called by muse, mutect2, varscan2
- TTC39A | c.1782C>G p.L594= (on ENST00000447632 / NM_001297665.1; = p.L559= on NM_001080494.3) | Silent (SNP) | VAF 26/105 reads (25%) | catalogued as rs772365533, COSV99397195; called by muse, mutect2, varscan2
- UBA6 | c.1869A>G p.P623= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV100451980; called by muse, mutect2, varscan2
- UNC79 | c.1302G>A p.T434= (on ENST00000393151 / NM_001346218.2; = p.T257= on NM_020818.5) | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV56387929; called by muse, mutect2, varscan2
- UNC93A | c.528C>T p.S176= | Silent (SNP) | VAF 96/208 reads (46%) | catalogued as COSV100023738; called by muse, mutect2, varscan2
- UTRN | c.3219G>C p.L1073= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV100840738; called by muse, mutect2, varscan2
- VPS53 | c.1599C>G p.L533= (on ENST00000571805 / NM_001366253.2; = p.L504= on NM_018289.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV99346878; called by muse, mutect2, varscan2
- XDH | c.1761C>T p.A587= | Silent (SNP) | VAF 41/283 reads (14%) | catalogued as COSV65150502; called by muse, mutect2, varscan2
- ZFPM1 | c.864C>T p.N288= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as COSV100128832; called by muse, mutect2, varscan2
- ZNF304 | c.384C>T p.F128= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs1341620510, COSV56587167; called by muse, mutect2, varscan2
- ZNF407 | c.1161C>A p.T387= | Silent (SNP) | VAF 38/65 reads (58%) | catalogued as COSV99997013; called by muse, mutect2, varscan2
- ZNF536 | c.1690C>A p.R564= | Silent (SNP) | VAF 35/145 reads (24%) | catalogued as COSV62823213; called by muse, mutect2, varscan2
- ZNF554 | c.1308C>T p.Y436= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs368121318; called by muse, mutect2, varscan2
- ZNF677 | c.747A>G p.L249= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV100448232; called by mutect2, varscan2
- ZNHIT2 | c.834G>A p.P278= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs763637384, COSV99659436; called by muse, mutect2, varscan2
- AC133065.1 | n.439-1449G>T | Intron (SNP) | VAF 6/12 reads (50%) | catalogued as rs1458844433; called by muse, mutect2, varscan2
- ALDH3A1 | chr17:19748341 G>C | 5'Flank (SNP) | VAF 15/44 reads (34%) | catalogued as COSV99856072; called by muse, mutect2, varscan2
- BIRC8 | n.1457A>T | RNA (SNP) | VAF 32/146 reads (22%) | catalogued as COSV101461373; called by muse, varscan2
- CEP295 | chr11:93732124 G>C | 3'Flank (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1737G>A | RNA (SNP) | VAF 18/113 reads (16%) | called by muse, mutect2, varscan2
- MIR516B2 | n.70G>T | RNA (SNP) | VAF 7/30 reads (23%) | catalogued as rs760158839; called by muse, mutect2, varscan2
- MIR518C | n.39A>G | RNA (SNP) | VAF 27/91 reads (30%) | called by muse, mutect2, varscan2
- RPS8 | c.388-93G>A | Intron (SNP) | VAF 31/102 reads (30%) | catalogued as COSV100785511; called by muse, mutect2, varscan2
- TPM4 | c.*252G>A | 3'UTR (SNP) | VAF 37/76 reads (49%) | catalogued as COSV99959570; called by muse, mutect2, varscan2
- TTN | c.10360+4152A>C | Intron (SNP) | VAF 10/21 reads (48%) | catalogued as COSV100634309, COSV60372174; called by muse, mutect2, varscan2
